Somatic mutation profile of tumor specimen TCGA-BP-4967-01A (aliquot TCGA-BP-4967-01A-01D-1462-08) from TCGA case TCGA-BP-4967, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 76.3 years (27,857 days).
Specimen TCGA-BP-4967-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e205904-e3b9-489d-9ad3-c95cb26ca412.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4967-11A (Solid Tissue Normal), aliquot TCGA-BP-4967-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38f716d4-bd88-49f3-8a0b-8e69e5b19d85

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 17, Frame Shift Del 6, Frame Shift Ins 5, Nonsense Mutation 2, Intron 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGO3 | c.1607T>G p.V536G | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55793788; called by muse, mutect2, varscan2
- AMY1C | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as rs763143846, COSV100915192; called by muse, varscan2
- ATF7IP | c.2287G>C p.A763P | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV53771820; called by muse, mutect2, varscan2
- C6orf89 | c.452C>A p.P151H (on ENST00000373685; = p.P158H on NM_152734.4) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV62102027; called by muse, mutect2, varscan2
- CEP192 | c.7235A>C p.H2412P | Missense Mutation (SNP) | VAF 110/296 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58065183; called by muse, mutect2, varscan2
- CFTR | c.2148G>T p.K716N | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV50058478; called by muse, mutect2, varscan2
- CHIT1 | c.833A>T p.D278V | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs775467175, COSV55147187; called by muse, mutect2, varscan2
- CNKSR2 | c.2774G>T p.G925V | Missense Mutation (SNP) | VAF 140/176 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV65334478; called by muse, mutect2, varscan2
- CSMD3 | c.9605G>A p.G3202D (on ENST00000297405 / NM_001363185.1; = p.G3033D on NM_052900.3) | Missense Mutation (SNP) | VAF 91/141 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52196449; called by muse, mutect2, varscan2
- CYFIP2 | c.3212T>G p.M1071R (on ENST00000616178 / NM_001291722.2; = p.M1046R on NM_014376.4) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as COSV59039936; called by muse, mutect2, varscan2
- CYP46A1 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55894832; called by muse, mutect2, varscan2
- FSCN1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61017753; called by muse, mutect2, varscan2
- GAGE12J | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 208/505 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV68163933; called by muse, mutect2, varscan2
- GPM6B | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as COSV57422587, COSV57422689; called by muse, mutect2
- HK1 | c.225T>C p.S75= | Splice Region (SNP) | VAF 37/96 reads (39%) | catalogued as COSV53859264; called by muse, mutect2, varscan2
- IRX3 | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV61668322; called by muse, mutect2, varscan2
- ITGA1 | c.2560A>T p.N854Y | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50883619; called by muse, mutect2, varscan2
- KIF13A | c.619C>G p.R207G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52453220; called by muse, varscan2
- MAGEE1 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 53/69 reads (77%) | catalogued as COSV63910532; called by muse, mutect2, varscan2
- MTHFD1 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV53700848; called by muse, mutect2, varscan2
- MYO1E | c.2044G>C p.E682Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55688478, COSV55695115; called by muse, mutect2, varscan2
- NEB | c.18617del p.E6206Gfs*23 | Frame Shift Del (DEL) | VAF 150/276 reads (54%) | catalogued as COSV51422113; called by mutect2, pindel, varscan2
- OGA | c.1898A>G p.N633S | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63381949; called by muse, mutect2, varscan2
- PAIP1 | c.650T>A p.M217K | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV59086173; called by muse, mutect2, varscan2
- PER1 | c.2224A>T p.I742F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV57919808; called by muse, mutect2, varscan2
- RABGAP1L | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs533934955, COSV52298774; called by muse, mutect2, varscan2
- RIMKLA | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 165/520 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV68909685, COSV68909795; called by muse, mutect2, varscan2
- RINL | c.727G>A p.E243K (on ENST00000591812 / NM_001195833.2; = p.E129K on NM_198445.4) | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV61574321; called by muse, mutect2, varscan2
- RNASE8 | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 86/125 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV57551608; called by muse, varscan2
- RPL5 | c.132C>A p.Y44* | Nonsense Mutation (SNP) | VAF 25/91 reads (27%) | catalogued as COSV59873544; called by muse, mutect2, varscan2
- RXRG | c.502A>G p.R168G | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63232240; called by muse, mutect2, varscan2
- SEC24A | c.144A>C p.Q48H | Missense Mutation (SNP) | VAF 352/724 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as COSV59747551, COSV59748728; called by muse, mutect2, varscan2
- SERPINA10 | c.1091T>C p.F364S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56228546; called by muse, mutect2
- SEZ6 | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.968); catalogued as COSV57980583; called by muse, mutect2, varscan2
- SLC7A14 | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51582951; called by muse, mutect2, varscan2
- SOS1 | c.3308G>A p.S1103N | Missense Mutation (SNP) | VAF 103/141 reads (73%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.954); catalogued as COSV67675524; called by muse, mutect2, varscan2
- SPDEF | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148079586, COSV55058369; called by muse, mutect2, varscan2
- SPSB3 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs150535227; called by muse, mutect2, varscan2
- TXLNA | c.244A>C p.I82L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV65314571; called by muse, mutect2, varscan2
- VHL | c.406T>G p.F136V | Missense Mutation (SNP) | VAF 225/299 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56544566, COSV56552648; called by muse, mutect2, varscan2
- ZDHHC22 | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1233138722, COSV60058415; called by muse, mutect2, varscan2
- ZIC5 | c.1361A>G p.E454G | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57437831; called by muse, mutect2, varscan2
- GPRASP1 | c.3974dup p.F1326Lfs*2 | Frame Shift Ins (INS) | VAF 111/176 reads (63%) | called by mutect2, pindel, varscan2
- MAP9 | c.913dup p.S305Kfs*6 | Frame Shift Ins (INS) | VAF 95/166 reads (57%) | called by mutect2, pindel, varscan2
- MDN1 | c.11017dup p.L3673Pfs*5 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- PELP1 | c.1472del p.P491Lfs*7 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- PRKD2 | c.2518_2527del p.F840Sfs*61 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- PTPDC1 | c.2227dup p.R743Kfs*9 (on ENST00000375360 / NM_177995.3; = p.R795Kfs*9 on NM_152422.4) | Frame Shift Ins (INS) | VAF 31/63 reads (49%) | called by mutect2, pindel, varscan2
- PTPRC | c.1649del p.Y550Sfs*30 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- SLITRK4 | c.1867_1870del p.I624* | Frame Shift Del (DEL) | VAF 97/126 reads (77%) | called by mutect2, pindel, varscan2
- TMEM74B | c.80dup p.P28Sfs*43 | Frame Shift Ins (INS) | VAF 41/116 reads (35%) | called by mutect2, pindel, varscan2
- WWC2 | c.1116del p.E372Dfs*3 | Frame Shift Del (DEL) | VAF 25/46 reads (54%) | called by mutect2, pindel, varscan2
- AHDC1 | c.4365C>T p.H1455= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV55939330; called by muse, mutect2, varscan2
- BTBD2 | c.570G>A p.V190= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV55309097; called by muse, mutect2, varscan2
- CHST9 | c.1215C>A p.T405= | Silent (SNP) | VAF 73/258 reads (28%) | catalogued as COSV52438567; called by muse, mutect2, varscan2
- CYP7A1 | c.1239T>G p.L413= | Silent (SNP) | VAF 65/119 reads (55%) | catalogued as CD021814, COSV56963925; called by muse, mutect2, varscan2
- ITGA10 | c.1713G>A p.A571= | Silent (SNP) | VAF 80/205 reads (39%) | catalogued as rs782328114, COSV65197625; called by muse, varscan2
- ITM2A | c.547C>T p.L183= | Silent (SNP) | VAF 77/88 reads (88%) | catalogued as COSV64811115; called by muse, mutect2, varscan2
- KCNK2 | c.1050G>A p.E350= (on ENST00000444842 / NM_001017425.3; = p.E335= on NM_014217.4) | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV67206463; called by muse, mutect2, varscan2
- KMT2D | c.13449G>A p.L4483= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs376096667, COSV56447052; called by muse, varscan2
- MDN1 | c.3804C>A p.G1268= | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2
- NELL2 | c.1821G>A p.G607= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV61576185; called by muse, mutect2, varscan2
- SLC12A4 | c.2880G>T p.L960= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV50452936; called by muse, mutect2, varscan2
- SPECC1 | c.1911C>T p.A637= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs373578290; called by muse, mutect2, varscan2
- STAT5B | c.1935T>C p.P645= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs767238307, COSV53183035; called by muse, mutect2, varscan2
- TMEM150A | c.195C>A p.L65= (on ENST00000334462 / NM_001031738.3; = p.S35* on NM_153342.3) | Silent (SNP) | VAF 44/67 reads (66%) | catalogued as COSV57818046; called by muse, mutect2, varscan2
- USP8 | c.708A>G p.E236= | Silent (SNP) | VAF 51/149 reads (34%) | catalogued as COSV56164793; called by muse, mutect2, varscan2
- ZFPM2 | c.1164C>T p.S388= | Silent (SNP) | VAF 61/101 reads (60%) | catalogued as rs376392532; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZIM3 | c.942G>A p.K314= | Silent (SNP) | VAF 86/383 reads (22%) | catalogued as COSV54143317; called by muse, mutect2, varscan2
- MIR30C2 | n.16_22delinsT | RNA (DEL) | VAF 26/118 reads (22%) | called by pindel, varscan2*
- SRSF6 | c.257-490A>G | Intron (SNP) | VAF 92/185 reads (50%) | catalogued as COSV54827880; called by muse, mutect2, varscan2
- XBP1 | c.227+266G>C | Intron (SNP) | VAF 48/69 reads (70%) | catalogued as COSV99321568; called by muse, mutect2, varscan2
